Gene-level copy-number profile of tumor specimen AP-67ZV-EQ from APOLLO case AP-67ZV, project APOLLO-LUAD (APOLLO1: Proteogenomic characterization of lung adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3.
Specimen AP-67ZV-EQ: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file d1a16d8c-99d1-43a2-b0dc-a89a94d3c1e3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator AP-67ZV-WA (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/f7e7ddc7-439b-4f0e-aa03-c3ff1fcaf5f1

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 216; copy number 1: 17,057; copy number 2: 35,657; copy number 3: 5,958; copy number 4: 14; copy number 5: 4.

Homozygous deletions (total copy number 0; autosomes only): 90 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:23,872,268–24,200,849, 16 genes (within-gene range 0–1): PGAM1P6, RPS13P4, UBXN2A, SDHCP3, RN7SL610P, MFSD2B, WDCP, RNU6-370P, FKBP1B, SF3B6, FAM228B, TP53I3, PFN4, AC008073.3, AC008073.2, FAM228A.
- chr2:42,440,377–42,756,947, 9 genes (within-gene range 0–1): AC025750.2, KCNG3, VDAC1P13, RPS13P3, MTA3, Metazoa_SRP, AC025750.1, AC074375.1, RNU6-137P.
- chr3:90,261,414–93,843,862, 2 genes: HSPE1P19, RNU6-488P.
- chr4:49,203,171–49,589,529, 19 genes: AC118282.3, AC118282.2, AC118282.4, SNX18P23, AC118282.1, MTCO3P39, MTND3P22, AC119751.3, ANKRD20A17P, AC119751.5, AC119751.2, AC119751.8, AC119751.7, MTCO3P42, AC119751.1, AC119751.6, SNX18P24, AC119751.4, SNX18P25.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr9:40,755,407–40,883,763, 4 genes: AL353626.3, RNU6-156P, AL353626.1, AL353626.2.
- chr10:38,403,189–38,452,153, 1 gene (within-gene range 0–2): AL133216.2.
- chr10:38,452,987–42,281,819, 15 genes: CICP9, AL133216.1, ABCD1P2, AL133173.2, PABPC1P12, SLC9B1P3, ACTR3BP5, CHEK2P5, AL133173.1, AL590623.1, KSR1P1, IGKV1OR10-1, AL031601.1, AL031601.2, PABPC1P8.
- chr11:50,170,156–50,422,316, 9 genes: AC109635.3, AC109635.6, PHKG1P3, AC109635.4, AC109635.2, AC109635.1, LINC02750, AC024405.2, AC024405.1.
- chr20:51,596,514–52,204,308, 9 genes: ATP9A, AL138807.1, SALL4, LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1.
- chr21:12,999,676–13,016,692, 1 gene: AP001464.1.
- chr21:44,350,163–44,443,081, 4 genes (within-gene range 0–1): TRPM2, TRPM2-AS, AP001065.2, AP001065.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:177,438,503–177,479,656, 4 genes, copy number 5 (within-gene range 3–5): PRR7-AS1, PRR7, DBN1, AC145098.2.

Autosomal genes at a single copy (total copy number 1): 14,327. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
